Surgical pathology report (de-identified scan), TCGA case TCGA-46-3767, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site St. Joseph's Medical Center (MD), specimen TCGA-46-3767-01A (Primary Tumor).

[page 1 of 4]
TIENT:

TISSUES:

- A. LYMPH NODE
- B. LYMPH NODE

CODES: P88305 - 88305
P88307 - 88307
P88331 - 88331
D50175 - RESECTION
D50177 - REGIONAL LYMPH
88305TC - LEVEL IV - GROS
88307TC - LEVEL V - GROSS
88331TC - PATHOLOGY CONSU
1 - SURGICAL SPECIM
T28700 - LT LO LOBE LUNG
T28700|M941 - LT LO LOBE LUNG|SQUAMOUS CARCIN
T08000 - LYMPH NODE

ICD CODES: 162.5 - MAL NEO LOWER LOBE LUNG

MARKERS: 88305, 88305TC, 88307, 88307TC, 88331, PATH CONSULT FS, RES, RLN, SURGICAL SPECIMEN

[page 2 of 4]
CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: HISTORY OF LEFT LUNG CA.

FINAL DIAGNOSIS

- A. MEDIASTINAL LYMPH NODES, 9L: TWO LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY.
- B. MEDIASTINAL LYMPH NODE, UPPER 9L: SINGLE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY.
- C. LOWER LOBE, LEFT LUNG (WEDGE RESECTION): MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA, GRADE II, 1.5 CM MAXIMUM DIAMETER. THE TUMOR IS CONFINED WITHIN THE LUNG, AND EXTENDS TO WITHIN 2.2 CM OF THE INKED PARENCHYMAL MARGIN AT ITS CLOSEST APPROACH.

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "9L" and consists of two anthracotic lymph nodes measuring 0.3 and 0.7 cm in dimension, each of which is submitted entirely intact, 2 (1) for frozen section labeled "FSP".

FROZEN SECTION DIAGNOSIS: Lymph nodes, 9L: No tumor identified.

B. The specimen is submitted fresh for frozen section as "upper 9L" and consists of one anthracotic lymph node measuring 0.7 cm in greatest dimension which is submitted in toto, 1 (1) labeled "FSP".

FROZEN SECTION DIAGNOSIS: Lymph node, upper 9L: No tumor identified.

C. The specimen is submitted fresh but not for frozen section as "left lower lobe lung wedge" and consists of a 40 gram (formalin fixed), 11.5 x 4.5 x 2.5 cm lung wedge received with three stapled margins measuring 3 to 5 cm in length. The pleural surface shows an ill defined firm puckered

Continued on next page ...

[page 3 of 4]
GROSS DESCRIPTION

(Continued)

area surrounded by white to tan membranous adhesions. The pleural surface overlying this area is inked blue. The stapled margin is removed and the underlying parenchyma inked black. Sectioning reveals a 1.5 x 1.3 x 0.8 cm ill defined tan white focally gray firm mass corresponding to the previously described puckered and indurated area on the pleural surface measuring 0.2 cm from the pleural surface and 2.2 cm from the black inked parenchyma underlying the stapled resection margin. The remaining parenchyma is tan pink to red, spongy, homogenous and grossly unremarkable. No other discrete masses or nodularities are grossly identified. Representative sections are submitted, multiple (5) as follows:

- 1: Mass with closest pleural surface.
- 2: Additional section of mass with adjacent uninvolved parenchyma.
- 3: Perpendicular sections of the parenchyma underlying the stapled margin closest to mass.
- 4: Uninvolved parenchyma with membranous and pleural adhesions.
- 5: Uninvolved pleura and parenchymal surface.

PRIORITY

PRIORITY: FROZEN SEC

SURGICAL PROCEDURES:

RESECTION, REGIONAL LYMPH

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: WEDGE RESECTION
LATERALITY: LEFT
TUMOR SITE: LOWER LOBE
TUMOR SIZE: 1.5 CM
HISTOLOGIC TYPE: SQUAMOUS
HISTOLOGIC GRADE: II
EXTENT OF INVASION: CONFINED TO LUNG

Continued on next page ...

[page 4 of 4]
SYNOPTIC REPORT

(Continued)

EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): NONE
ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC: (SEE
NARRATIVE)

MARGINS:

BRONCHIAL: N/A

PARENCHYMAL: UNINVOLVED

VASCULAR: N/A

DISTANCE TO PERTINENT MARGIN(S) (AS APPLICABLE): 2.2 CM FROM PARENCHYMAL
MARGIN

VENOUS INVASION: ABSENT
ARTERIAL (LARGE VESSEL) INVASION: ABSENT

LYMPH NODE (INCLUDING 09:S14483):

N1 - # INVOLVED/# EXAMINED: N/A

N2 - # INVOLVED/#EXAMINED: 0/10+

N3 - # INVOLVED/# EXAMINED: 0/6+

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

PTNM STAGE: pT1a N0 MX

*** End of Report ***

Source: NCI Genomic Data Commons file 4093542e-17d6-422f-8aaa-892430254cc0 (TCGA-46-3767.8E91EE2E-DA06-49FE-AA5E-4FACA1240A25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).